Somatic mutation profile of tumor specimen TARGET-10-PARFAP-09A (aliquot TARGET-10-PARFAP-09A-01D) from TARGET case TARGET-10-PARFAP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,040 days).
Specimen TARGET-10-PARFAP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9e3eb82-3a83-4c91-858c-d41d1d9d27ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFAP-14A (Bone Marrow Normal), aliquot TARGET-10-PARFAP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1b7dc1a-8b5f-4089-9287-e420775a4276

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C12orf60 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs977514400, COSV57452057; called by muse, mutect2, varscan2
- DLG2 | c.1978C>T p.R660* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as rs747209072, COSV54641039; called by muse, mutect2, varscan2
- CPXCR1 | c.584C>A p.T195K | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAXDC2 | c.*140C>T | 3'UTR (SNP) | VAF 15/105 reads (14%) | catalogued as rs958900474; called by muse, mutect2, varscan2
- SLIT3 | c.1973+27C>T | Intron (SNP) | VAF 6/50 reads (12%) | catalogued as rs200423009; called by muse, mutect2, varscan2
